CCDI case PBCAHU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Specialized Gonadal Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/6150deee-94d7-42a9-8b2f-5e92cc7e856d

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Sex cord-gonadal stromal tumor, incompletely differentiated: ICD-O-3 morphology code: 8591/1; Tissue or organ of origin: Ovary; Age at diagnosis: 14.7 years (5,379 days).

Biospecimens (3 samples)
- Sample 0DMKKI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMKKT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMKN4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
